FM case AD9911 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/c706b47c-815d-41d4-8a83-18495f427191

Female, 62.8 years: Papillary serous adenocarcinoma (ICD-O-3 8460/3) of the uterus; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
